Somatic mutation profile of tumor specimen 0DLJX5 from CCDI case PBBZLU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, small cell, nonkeratinizing; Tissue or organ of origin: Nasopharynx, NOS; Age at diagnosis: 14.0 years (5,130 days).
Specimen 0DLJX5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4b00840-78f4-4778-bf17-9f24ea12612f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLJWR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b15914c1-6ab5-448a-9dc3-3692d1c4cac3

The open-access MAF lists 80 somatic variants for this specimen: 52 protein-altering or splice-affecting, 15 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 15, Nonsense Mutation 6, Intron 5, 5'UTR 3, 3'UTR 3, 5'Flank 1, RNA 1, In Frame Ins 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 139/1145 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACKR2 | c.817C>T p.H273Y | Missense Mutation (SNP) | VAF 113/897 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.767); catalogued as rs745405456; called by muse, mutect2, varscan2
- ASXL1 | c.2338C>T p.Q780* | Nonsense Mutation (SNP) | VAF 90/906 reads (10%) | catalogued as rs751021760, COSV100041544, COSV60107863, COSV60122626; called by muse, mutect2, varscan2
- BIRC6 | c.6445C>T p.L2149F | Missense Mutation (SNP) | VAF 217/1677 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1394783536; called by muse, mutect2, varscan2
- CCDC63 | c.1022C>T p.T341M | Missense Mutation (SNP) | VAF 116/985 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as rs149841694; called by muse, mutect2, varscan2
- CCDC9 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 97/835 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs376833190; called by muse, mutect2, varscan2
- CLK4 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 162/1246 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.011); catalogued as rs1303687829; called by muse, mutect2, varscan2
- DICER1 | c.3991C>G p.L1331V | Missense Mutation (SNP) | VAF 208/1892 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV58629588; called by muse, mutect2, varscan2
- EP300 | c.6970dup p.H2324Pfs*55 | Frame Shift Ins (INS) | VAF 52/414 reads (13%) | catalogued as rs754418509; called by mutect2, varscan2
- GATM | c.530A>G p.N177S | Missense Mutation (SNP) | VAF 218/1618 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs1476714481; called by muse, mutect2, varscan2
- GDF7 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 86/516 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55347714; called by muse, mutect2, varscan2
- GRM5 | c.2858C>A p.P953H (on ENST00000305447 / NM_001143831.2; = p.P921H on NM_000842.4) | Missense Mutation (SNP) | VAF 34/888 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.174); catalogued as COSV59594767; called by muse, mutect2
- INTS9 | c.1755G>T p.L585F | Missense Mutation (SNP) | VAF 219/1651 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.23); catalogued as COSV68436245; called by muse, mutect2, varscan2
- LONRF2 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 166/976 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV66541243; called by muse, mutect2, varscan2
- NISCH | c.4309G>A p.V1437M | Missense Mutation (SNP) | VAF 154/1315 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs753661023, COSV58741847; called by muse, varscan2
- OBSCN | c.9257C>T p.S3086L | Missense Mutation (SNP) | VAF 76/648 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.876); catalogued as rs748548692; called by muse, mutect2, varscan2
- P3H1 | c.86G>A p.G29E | Missense Mutation (SNP) | VAF 99/685 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV52536191; called by muse, mutect2, varscan2
- PLEKHG2 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 120/962 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs777862067; called by muse, mutect2, varscan2
- RTEL1 | c.2588C>T p.S863F | Missense Mutation (SNP) | VAF 112/886 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1029017182; called by muse, mutect2, varscan2
- SBK1 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 162/1169 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.27); catalogued as rs140773263; called by muse, mutect2, varscan2
- SBNO2 | c.3692G>A p.R1231K | Missense Mutation (SNP) | VAF 77/575 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1331340193; called by muse, mutect2, varscan2
- STXBP5L | c.2770G>A p.E924K | Missense Mutation (SNP) | VAF 52/1964 reads (3%) | SIFT tolerated (0.36); PolyPhen benign (0.32); catalogued as COSV99876112; called by muse, mutect2
- TCHH | c.2755G>A p.E919K | Missense Mutation (SNP) | VAF 166/1271 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as rs1293934764, COSV64273085; called by muse, mutect2, varscan2
- TMCO3 | c.1606C>T p.Q536* | Nonsense Mutation (SNP) | VAF 92/919 reads (10%) | catalogued as COSV64806978; called by muse, mutect2, varscan2
- ZEB1 | c.901C>T p.R301* | Nonsense Mutation (SNP) | VAF 226/1885 reads (12%) | catalogued as rs1263636689, COSV58042543; called by muse, mutect2, varscan2
- ZSCAN10 | c.1712G>A p.R571H (on ENST00000252463; = p.R626H on NM_032805.3) | Missense Mutation (SNP) | VAF 93/657 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as rs1195593327; called by mutect2, varscan2
- BARD1 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 240/2038 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- CBX1 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 199/1390 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- CNST | c.1697A>G p.E566G | Missense Mutation (SNP) | VAF 64/1730 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2
- COLEC12 | c.1297C>T p.Q433* | Nonsense Mutation (SNP) | VAF 87/862 reads (10%) | called by muse, mutect2, varscan2
- DENND2B | c.2092G>A p.E698K | Missense Mutation (SNP) | VAF 114/1762 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2
- FGF17 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 162/1658 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GLUD1 | c.590A>T p.E197V | Missense Mutation (SNP) | VAF 120/1287 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GLUD1 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 116/1276 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IZUMO3 | c.125C>T p.S42L | Missense Mutation (SNP) | VAF 193/1619 reads (12%) | SIFT tolerated (0.45); called by muse, mutect2, varscan2
- KANK1 | c.49_50insGTA p.D17delinsGN | In Frame Ins (INS) | VAF 142/1153 reads (12%) | called by mutect2, varscan2
- MRC1 | c.3446C>A p.S1149Y | Missense Mutation (SNP) | VAF 194/1750 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYCBP2 | c.13882G>T p.A4628S (on ENST00000357337; = p.A4666S on NM_015057.5) | Missense Mutation (SNP) | VAF 131/1125 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PEG3 | c.3811G>A p.E1271K | Missense Mutation (SNP) | VAF 148/1250 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- SENP7 | c.2771C>T p.S924L | Missense Mutation (SNP) | VAF 158/1713 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.343); called by muse, mutect2
- SLC24A5 | c.842G>T p.S281I | Missense Mutation (SNP) | VAF 137/1207 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLC33A1 | c.1457A>C p.N486T | Missense Mutation (SNP) | VAF 217/1645 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TCTEX1D4 | c.40G>T p.E14* | Nonsense Mutation (SNP) | VAF 85/679 reads (13%) | called by muse, mutect2, varscan2
- TET2 | c.3829G>C p.D1277H | Missense Mutation (SNP) | VAF 200/1857 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- TFAP2D | c.158C>A p.T53N | Missense Mutation (SNP) | VAF 104/1613 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.362); called by muse, mutect2
- TMEM156 | c.821C>G p.S274* | Nonsense Mutation (SNP) | VAF 96/1412 reads (7%) | called by muse, mutect2
- TRAM1 | c.346C>T p.H116Y | Missense Mutation (SNP) | VAF 189/1808 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- TRIM65 | c.775C>T p.L259F | Missense Mutation (SNP) | VAF 117/963 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TSPO | c.235G>T p.V79L | Missense Mutation (SNP) | VAF 56/1452 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.015); called by muse, mutect2
- USH2A | c.13933G>A p.A4645T | Missense Mutation (SNP) | VAF 71/2080 reads (3%) | SIFT tolerated (0.52); PolyPhen benign (0.014); called by muse, mutect2
- WDR81 | c.410G>T p.R137L | Missense Mutation (SNP) | VAF 29/1094 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.02); called by muse, mutect2
- ZNF618 | c.2596G>A p.D866N (on ENST00000374126 / NM_001318042.2; = p.D773N on NM_133374.2) | Missense Mutation (SNP) | VAF 137/1149 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AGR2 | c.513G>T p.L171= | Silent (SNP) | VAF 105/1051 reads (10%) | called by muse, mutect2, varscan2
- ALDOA | c.783G>A p.E261= (on ENST00000642816 / NM_001243177.4; = p.E207= on NM_184041.5) | Silent (SNP) | VAF 110/875 reads (13%) | called by muse, mutect2, varscan2
- CAPN3 | c.2286C>A p.L762= | Silent (SNP) | VAF 94/909 reads (10%) | catalogued as COSV99782111; called by muse, mutect2, varscan2
- CHD9 | c.3183G>A p.L1061= | Silent (SNP) | VAF 180/1572 reads (11%) | called by muse, mutect2, varscan2
- MCUR1 | c.669G>A p.Q223= | Silent (SNP) | VAF 185/1690 reads (11%) | called by muse, mutect2, varscan2
- NETO1 | c.894C>T p.F298= | Silent (SNP) | VAF 102/1200 reads (9%) | called by muse, mutect2
- PCSK9 | c.915G>A p.A305= | Silent (SNP) | VAF 111/701 reads (16%) | catalogued as rs1283644480, CM1213459; called by muse, mutect2, varscan2
- PLXNA1 | c.1086C>T p.L362= | Silent (SNP) | VAF 80/580 reads (14%) | called by muse, mutect2, varscan2
- RELN | c.6759C>T p.N2253= | Silent (SNP) | VAF 210/1808 reads (12%) | catalogued as rs548135273, COSV59008995; ClinVar: likely benign; called by muse, mutect2, varscan2
- SNAI3 | c.349C>T p.L117= | Silent (SNP) | VAF 128/960 reads (13%) | called by muse, mutect2, varscan2
- TPBGL | c.147C>T p.L49= | Silent (SNP) | VAF 74/394 reads (19%) | called by muse, mutect2, varscan2
- TSC22D2 | c.981G>A p.T327= | Silent (SNP) | VAF 88/1164 reads (8%) | called by muse, mutect2
- UPK3B | c.786C>T p.P262= (on ENST00000257632; = p.P234L on NM_001347684.2) | Silent (SNP) | VAF 130/1022 reads (13%) | catalogued as COSV99991089; called by muse, mutect2, varscan2
- ZNF532 | c.3448C>T p.L1150= | Silent (SNP) | VAF 135/1125 reads (12%) | called by muse, mutect2
- ZSWIM9 | c.819C>T p.F273= | Silent (SNP) | VAF 81/719 reads (11%) | called by muse, mutect2, varscan2
- ANKRD37 | c.-19C>T | 5'UTR (SNP) | VAF 151/1378 reads (11%) | catalogued as rs750137008, COSV52992613; called by muse, mutect2, varscan2
- ARPC5L | c.-11G>A | 5'UTR (SNP) | VAF 92/638 reads (14%) | catalogued as rs772158606; called by muse, mutect2, varscan2
- CAV2 | c.338+74C>G | Intron (SNP) | VAF 43/318 reads (14%) | called by muse, mutect2, varscan2
- CDH5 | c.*2C>T | 3'UTR (SNP) | VAF 171/1431 reads (12%) | catalogued as rs1267148293, COSV58516865; called by muse, mutect2, varscan2
- JMJD8 | c.*660G>T | 3'UTR (SNP) | VAF 48/654 reads (7%) | called by muse, mutect2
- KLC4 | c.1745+35G>A | Intron (SNP) | VAF 45/346 reads (13%) | catalogued as rs377192744; called by muse, mutect2, varscan2
- LAMA1 | c.233-36C>T | Intron (SNP) | VAF 42/320 reads (13%) | catalogued as rs369661634; called by muse, mutect2, varscan2
- PHF10 | c.409+30C>G | Intron (SNP) | VAF 142/1442 reads (10%) | called by muse, mutect2
- PPP6C | c.-50C>T | 5'UTR (SNP) | VAF 37/282 reads (13%) | catalogued as rs376625505; called by muse, mutect2, varscan2
- RPUSD3 | chr3:9844024 G>C | 5'Flank (SNP) | VAF 135/1117 reads (12%) | called by muse, mutect2, varscan2
- SPTAN1 | c.6747+11G>A | Intron (SNP) | VAF 93/560 reads (17%) | catalogued as rs775553506; ClinVar: likely benign; called by muse, mutect2, varscan2
- SPTLC1 | c.*60C>T | 3'UTR (SNP) | VAF 139/1520 reads (9%) | catalogued as rs535778954; called by muse, mutect2
- SSPOP | n.11234G>T | RNA (SNP) | VAF 68/515 reads (13%) | called by muse, mutect2, varscan2
